Surgical pathology report (de-identified scan), TCGA case TCGA-QG-A5YV, project TCGA-COAD (Colon Adenocarcinoma), tissue source site BLN - Baylor, specimen TCGA-QG-A5YV-01A (Primary Tumor).

[page 1 of 8]
Surgical Pathology:

path

ECOD-0-3

Adenocarcinoma arising in a tubular villous
adenoma 8262/3

CCF Adenocarcinoma NOS 8140/3

Site: Sigmoid colon C18.7

JW 4/16/13

SURGICAL PATHOLOGY

Accession #:

ADDENDUM

Addendum Comment

The purpose of this addendum is to report results following deeper levels and an immunohistochemistry stain for Pancytokeratin on a lymph node in section G35 due to a small fibrotic focus seen on the routinely stained slide.

No metastatic carcinoma is seen in the additional deeper levels of the lymph node in section G35. An immunohistochemistry stain for Pancytokeratin is negative; the control is appropriate. The diagnoses remain unchanged.

This immunohistochemistry test(s) was developed and its performance characteristics determined by the Immunohistochemistry Laboratory and/or affiliated institution. It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

End of Addendum Report or Additional Results

Staff Pathologist

PATHOLOGIC DIAGNOSIS

A. SOFT TISSUE, LEFT ABDOMINAL WALL, EXCISIONAL BIOPSY:

- NO ADENOCARCINOMA FOUND
- EXTENSIVE FIBROSIS WITH CHRONIC INFLAMMATION INVOLVING

[page 2 of 8]
LOBULES OF ADIPOSE TISSUE COMPATIBLE WITH SCAR

B. URINARY BLADDER, LEFT MUCOSAL MARGIN, EXCISION:

- NO ADENOCARCINOMA FOUND
- UROTHELIAL MUCOSA WITH EDEMA, FOCAL HEMORRHAGE AND CHRONIC INFLAMMATION

C. URINARY BLADDER, POSTERIOR MUCOSA, EXCISION:

- NO ADENOCARCINOMA FOUND
- UROTHELIAL-TYPE MUCOSA WITH EDEMA, CHRONIC INFLAMMATION AND HEMORRHAGE

D. URINARY BLADDER, RIGHT MARGIN AND MUCOSA, EXCISION:

- NO ADENOCARCINOMA FOUND
- UROTHELIAL-TYPE MUCOSA WITH EDEMA, CHRONIC INFLAMMATION AND FOCAL HEMORRHAGE

E. URINARY BLADDER, POSTERIOR MUSCLE MARGIN, EXCISION:

- NO ADENOCARCINOMA SEEN
- SMOOTH MUSCLE FIBERS WITHIN AN EDEMATOUS, INFLAMED STROMA, COMPATIBLE WITH BLADDER WALL

F. SOFT TISSUE, UMBILICAL REGION, HERNIORRHAPHY:

- NO ADENOCARCINOMA SEEN
- COMPATIBLE WITH HERNIA SAC

G. SIGMOID COLON AND URINARY BLADDER, PARTIAL CYSTECTOMY AND SIGMOIDECTOMY EN BLOC RESECTION OF DOME OF UNINARY BLADDER AND POSTERIOR ABDOMINAL WALL:

- ADENOCARCIOMA, MODERATELY DIFFERENTIATED, ARISING IN A TUBULOVILLOUS ADENOMA
- SPECIMEN LENGTH: 31.0 CM
- TUMOR SITE: SIGMOID COLON
- TUMOR SIZE: GREATEST DIMENSION: 9.5 CM
- ADDITIONAL DIMENSIONS: 7.0 X 6.0 CM
- MACROSCOPIC TUMOR PERFORATION: CANNOT BE DETERMINED
- MICROSCOPIC TUMOR PERFORATION: PRESENT
- HISTOLOGIC GRADE: LOW-GRADE
- MICROSCOPIC TUMOR EXTENSION: TUMOR PENETRATES TO THE SURFACE OF THE VISCERAL PERITONEUM (Serosa) AND DIRECTLY INVADES ADJACENT STRUCTURES (URINARY BLADDER)
- MARGINS: DISTAL AND PROXIMAL MARGINS NEGATIVE
- TREATMENT EFFECT: NO PRIOR TREATMENT
- LYMPHOVASCULAR INVASION: NOT IDENTIFIED
- PERINEURAL INVASION: NOT IDENTIFIED
- TUMOR DEPOSITS (DISCONTINUOUS EXTRAMURAL EXTENSION): NOT IDENTIFIED

[page 3 of 8]
- METASTATIC ADENOCARCINOMA FOUND IN ONE OF THIRTY-ONE LYMPH NODES (1/31)
- ADDITIONAL FINDINGS:
- EXTENSIVE SEROSITIS, INCLUDING RESECTION MARGINS
- INTRAMURAL ABSCESS
- HEMORRHAGIC CYSTITIS
- TUBULOVILLOUS ADENOMATOUS CHANGE
- ANCILLARY STUDIES: NEGATIVE FOR MICROSATELLITE INSTABILITY (SEE PREVIOUS SURGICAL REPORT

H. SIGMOID COLON, NEW PROXIMAL MARGIN, EXCISION:

- NEGATIVE FOR ADENOCARCINOMA

I. SIGMOID COLON, NEW DISTAL MARGIN, EXCISION:

- NEGATIVE FOR ADENOCARCINOMA
- ACUTE SEROSITIS

J. LYMPH NODE, SITE NOT SPECIFIED, REGIONAL DISSECTION:

- TWO LYMPH NODES IDENTIFIED, BOTH NEGATIVE FOR METASTATIC ADENOCARCINOMA (0/2)

PATHOLOGIC STAGING (pTNM):

- PRIMARY TUMOR (pT): pT4b, TUMOR DIRECTLY INVADES OR IS ADHERENT TO OTHER ORGANS OR STRUCTURES
- REGIONAL LYMPH NODES (pN): pN1a, METASTASIS IN ONE REGIONAL LYMPH NODE (SEE COMMENT)
- NUMBER EXAMINED: THIRTY-THREE (33)
- NUMBER INVOLVED: ONE (1)
- DISTANT METASTASIS: NOT APPLICABLE

Staff Pathologist

Comment

Part G: A lymph node in section G35 contains a small suspicious fibrotic focus underlying the subcapsular sinus. Additional deeper levels are pending as well as a Pancytokeratin immunohistochemistry stain. These results will be issued in an addendum report.

Intraoperative Consultation

Intraoperative Frozen Section Diagnosis

FSA1-2: Soft tissue, left abdominal wall, excisional biopsy:

[page 4 of 8]
- Scarring and inflammation
- No metastatic carcinoma seen
- The diagnosis was verbally reported to

FSB: Urinary bladder, left mucosal margin, excision:

- No malignancy seen

FSC: Urinary bladder, posterior mucosa, excision:

- No malignancy seen

FSD: Urinary bladder, right mucosa margin, excision:

- No malignancy seen

FSE: Urinary bladder, posterior muscle margin, excision:

- No malignancy seen
- verbally notified of the diagnosis at

Staff Pathologist

Pathology Resident

Pertinent Clinical Information

Possible abdominal wall involvement by sigmoid colon carcinoma.

Gross Description

Specimen Material: A- Left abdominal wall, B- Left bladder mucosa margin, C- Posterior bladder mucosa, D- Right bladder margin bladder mucosa, E- Posterior bladder muscle margin, F- Hernia sac, G- Sigmoid colon and partial bladder, H- New proximal margin (sigmoid), I- New distal margin (sigmoid), J- Additional lymph node.

The case is received in ten parts, each labeled with the patient's name medical record number and given accession number

and it is accompanied by a requisition form labeled with the same name and accession number.

Part A: Received fresh for intraoperative consultation labeled "RULE OUT TUMOR LEFT ABDOMINAL WALL" is a 2.5 x 2.0 x 0.7 cm tan-pink, irregular, soft piece of tissue which is bisected to reveal a tan-white, homogeneous area grossly compatible with either fibrous tissue or tumoral implant. Touch preparations are performed and the entire specimen is submitted for frozen section in cassettes FSA1 and FSA2.

Part B: Received fresh for intraoperative consultation labeled "BLADDER LEFT MARGIN, BLADDER MUCOSA" is a 2.0 x 0.7 x 0.5 cm tan-pink to red, irregular piece of soft tissue which is entirely submitted for frozen

[page 5 of 8]
section in cassette FSB.

Part C: Received fresh for intraoperative consultation labeled "BLADDER POSTERIOR, BLADDER MUCOSA" is a 2.0 x 0.7 x 0.5 cm tan-pink to red, irregular soft piece of tissue which is entirely submitted for frozen section in cassette FSC.

Part D: Received fresh for intraoperative consultation labeled "BLADDER RIGHT MARGIN, BLADDER MUCOSA" is a 2.2 x 0.5 x 0.3 cm tan-pink to red, irregular soft piece of tissue which is entirely submitted for frozen section in cassette FSD.

Part E: Received fresh for intraoperative consultation labeled "BLADDER MUSCLE MARGIN, FROZEN SECTION" and consists of a 2.0 x 1.1 x 0.3 cm tan-pink to red, irregular piece of soft tissue which is entirely submitted for frozen section in cassette FSE.

Pathology Resident

Part F: Received in formalin labeled "HERNIA SAC" is a 6.0 x 6.0 x 3.5 cm tan-yellow, lobulated portion of adipose tissue with an attached fibrous membrane focally adherent to fat. The specimen is serially sectioned to reveal tan-yellow, lobulated and glistening adipose tissue with no grossly identifiable lesions. One representative section is submitted in cassette F.

Part G: Received in formalin labeled "SIGMOID COLON AND PARTIAL BLADDER" is a 31.0 cm in length and a diameter ranging from 5.0 to 6.5 cm segment of colon marked with a stitch indicating the proximal end, as oriented by the surgeon, with an attached 11.0 x 10.5 x 8.0 cm firm, round mass, displaying a 5.0 x 4.5 cm ovoid, hemorrhagic, irregular area most likely compatible with bladder mucosal resection margin (previously sent for frozen) located towards the distal colonic end. The specimen has an attached 28.0 x 19.0 x 1.5 cm portion of mesenteric fat.

The colonic serosa is tan-gray and granular adjacent to the bladder attachment site. Additionally there are multiple inconspicuous, thin, irregular foci of possible fibrin deposition disseminated all over the specimen. The mass has minimally attached adipose tissue with focal tan-gray granular areas of possible fibrin deposition.

There is a 9.5 x 6.0 cm tan-pink, focally friable, exophytic tumor involving the colonic mucosa circumferentially with focal areas of superficial necrosis and hemorrhage, located at 3.5 cm from the distal resection margin and at 15.0 cm from the proximal resection margin. A perpendicular section through the mass reveals continuity with the circumferential colonic mass

[page 6 of 8]
extending through a thick muscular wall, having up to 1.9 cm in thickness. This wall likely represents urinary bladder wall. The bulk mass of tumor present outside the colon measures 9.5 x 7.0 x 6.0 cm. The mass is grossly extending through the entire colonic wall thickness minimally penetrating grossly into the pericolic adipose tissue, at 0.5 cm from the serosal lining. The tumor infiltrates the muscular wall, at 1.5 cm from the bladder mucosal margin and at 0.4 cm from the outer bladder wall surface (purple ink) towards the proximal colon end.

Blue previous bladder resection site

Purple external mass

Black mesenteric serosa at the closest point of invasion

Section Code:

G1: distal resection margin, en face

G2-3: proximal resection margin, en face

G4-6: suspicious area of extension at superior aspect of mass adjacent to colon proximally

G7: deepest area of invasion into the mesenteric fat

G8: tumor invading the pericolic adipose tissue

G9: tumor with adjacent uninvolved mucosa at the distal end with underlying soft tissue abscess

G10: possible lymph node

G11-G16: representative sections of the previous bladder resection margin (perpendicular sections grossly uninvolved)

G17-G20: representative sections of tumor at the colonic location

G21-G22: colonic mucosa adjacent to tumor toward the proximal end

G23-G25: tumor in relation to the bladder wall

G26-G27: multiple whole possible lymph nodes

G28-G29: one serially sectioned possible lymph node

G30: one bisected lymph node

G31: multiple whole possible lymph nodes

G32: multiple whole possible lymph nodes

G33: one bisected lymph node

G34: multiple whole possible lymph nodes

G35: one bisected lymph node

G36: multiple whole possible lymph nodes

G37: one trisected lymph node

G38: one possible bisected lymph node

G39: multiple whole possible lymph nodes

G40-41: transition of tumor to bladder mucosa (orange ink towards the bladder)

G42-51: bladder mucosa (posterior portion towards the distal aspect of the colon)

G52-62: anterior aspect of the bladder mucosa (concluding submission of the bladder mucosa in its entirety)

G63-G68: bladder wall in relation with tumor and possible skeletal muscle

G69: tumor (orange indicates colonic luminal aspect)

[page 7 of 8]
G70-G73: tumor

G74: one bisected lymph node

G75: one bisected lymph node

G76: three possible whole lymph nodes

Part H: Received in formalin labeled "NEW PROXIMAL MARGIN (SIGMOID)" is a 5.0 x 0.8 x 0.7 cm portion of stapled fibroadipose tissue partially surfaced by mucosa, compatible with colonic origin. The staple line is removed and the remainder of the specimen is entirely submitted in a single cassette.

Part I: Received in formalin labeled "NEW DISTAL MARGIN (SIGMOID)" is a 3.1 x 0.7 x 0.7 cm stapled fragment of colonic mucosa. The staple line is removed and the remainder of the specimen is submitted in cassette I.

Part J: Received in formalin labeled "ADDITIONAL LYMPH NODE" is a 1.2 x 0.8 x 0.6 cm round, ovoid portion of tissue which is bisected to reveal a 0.7 cm tan-gray lymph node. The specimen is entirely submitted in cassette J.

Pathology Resident

Pathology Resident

Microscopic Description

A-F: Performed.

G: Sections show a moderately differentiated adenocarcinoma composed of highly irregular, tightly packed glandular structures with pleomorphic nuclei involved by extensive areas of necrosis, desmoplastic reaction and chronic inflammation. The tumor is surrounded by adenomatous colonic mucosa with tubulovillous architecture. The tumor seems to invade the sigmoid colon wall and penetrates into the muscular bladder wall extending close to the bladder mucosal urothelium, but without directly involving it. The bladder mucosa shows extensive hemorrhagic cystitis with subepithelial hemorrhage and congestion and extensive inflammatory infiltrate and edema within the mucosal lamina propria. There is extensive acute serositis involving the peritoneum with submesothelial polymorphonuclear cells. This acute inflammatory process involves the resection margins, as well. An area of intramural colonic abscess is identified near the distal aspect underlying the tumor.

H-J: Performed.

This case was reviewed by the staff pathologist listed below.

[page 8 of 8]
Pathology Resident

Electronically Signed Out

Staff Pathologist

Criteria	W 2/22/13	Yes	No

Source: NCI Genomic Data Commons file 21776c2b-5f91-43f8-833d-a8839bd5dbfe (TCGA-QG-A5YV.DCBDBBD7-E408-4E5F-AF2B-95F4D01C7D5C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).